Somatic mutation profile of tumor specimen TCGA-OR-A5J2-01A (aliquot TCGA-OR-A5J2-01A-11D-A29I-10) from TCGA case TCGA-OR-A5J2, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 44.1 years (16,090 days).
Specimen TCGA-OR-A5J2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a3165a5-3fb9-4334-9d91-f04cdb5c381f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5J2-10A (Blood Derived Normal), aliquot TCGA-OR-A5J2-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77339f88-7048-4fdc-8572-4655ac6d81b3

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 6, Nonsense Mutation 4, Frame Shift Del 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BBS10 | c.306_309del p.D102Efs*6 | Frame Shift Del (DEL) | VAF 40/96 reads (42%) | catalogued as rs745497072; called by pindel, varscan2
- CLDN1 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.063); catalogued as rs373107390; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DISP3 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 53/59 reads (90%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.085); catalogued as rs1372854383, COSV53823625; called by muse, mutect2, varscan2
- GFRA1 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 9/215 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1005537154, COSV100815894, COSV62602441; called by muse, mutect2
- IGSF3 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 102/138 reads (74%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.565); catalogued as rs778095679; called by muse, varscan2
- LRP1B | c.7466G>T p.C2489F | Missense Mutation (SNP) | VAF 59/73 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67217011; called by muse, mutect2, varscan2
- NEK2 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs759517583; called by muse, mutect2, varscan2
- RELN | c.2117C>T p.T706I | Missense Mutation (SNP) | VAF 40/258 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV59032900; called by muse, mutect2, varscan2
- SEMA3E | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754754690, COSV57087131; ClinVar: uncertain significance; called by mutect2, varscan2
- SUGT1 | c.484G>T p.E162* (on ENST00000343788 / NM_001130912.3; = p.E130* on NM_006704.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as rs747889876; called by muse, mutect2, varscan2
- TENM1 | c.1180G>T p.G394* | Nonsense Mutation (SNP) | VAF 30/68 reads (44%) | catalogued as COSV100949745; called by muse, mutect2, varscan2
- ANKS3 | c.1959G>C p.W653C | Missense Mutation (SNP) | VAF 42/60 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- BCOR | c.4831G>T p.E1611* (on ENST00000378444 / NM_001123385.2; = p.E1577* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- CDCP1 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CNTN3 | c.2736G>T p.W912C | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CTNNB1 | c.89dup p.Y30* | Nonsense Mutation (INS) | VAF 102/257 reads (40%) | called by mutect2, pindel, varscan2
- FAM9A | c.791A>T p.E264V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- FLNA | c.7689G>T p.K2563N (on ENST00000369850 / NM_001110556.2; = p.K2555N on NM_001456.3) | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- HECTD1 | c.4304T>A p.V1435D | Missense Mutation (SNP) | VAF 156/202 reads (77%) | SIFT tolerated (0.11); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- HIVEP2 | c.658A>G p.I220V | Missense Mutation (SNP) | VAF 77/109 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRP6 | c.3163G>A p.E1055K | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- PARP14 | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- RTEL1 | c.721G>T p.D241Y | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TP53 | c.502_515del p.H168Cfs*8 | Frame Shift Del (DEL) | VAF 37/58 reads (64%) | called by mutect2, pindel, varscan2
- ZNF230 | c.1420A>T p.M474L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- IZUMO1 | c.510G>A p.V170= | Silent (SNP) | VAF 70/88 reads (80%) | called by muse, mutect2, varscan2
- MRPL37 | c.957C>T p.G319= | Silent (SNP) | VAF 73/85 reads (86%) | called by muse, mutect2, varscan2
- TENT4A | c.2115C>T p.H705= | Silent (SNP) | VAF 75/91 reads (82%) | called by muse, mutect2, varscan2
- TGIF2LX | c.597C>A p.S199= | Silent (SNP) | VAF 121/319 reads (38%) | catalogued as COSV99383269; called by muse, mutect2, varscan2
- TLN2 | c.3183G>A p.T1061= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs1371356292, COSV60896243; called by muse, mutect2, varscan2
- UPK3A | c.714G>A p.G238= | Silent (SNP) | VAF 41/51 reads (80%) | catalogued as rs748691118; called by muse, mutect2, varscan2
- HSP90AB1 | c.*222T>G | 3'UTR (SNP) | VAF 39/47 reads (83%) | called by muse, mutect2, varscan2
